Somatic mutation profile of tumor specimen TCGA-DB-5273-01A (aliquot TCGA-DB-5273-01A-01D-1468-08) from TCGA case TCGA-DB-5273, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 33.3 years (12,152 days).
Specimen TCGA-DB-5273-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df7661dd-137a-4198-b2b6-f0aefa289195.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-5273-10A (Blood Derived Normal), aliquot TCGA-DB-5273-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de83787e-3950-46a0-9f6e-1cc7e22d8834

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 8, Silent 6, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/114 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 36/47 reads (77%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 162/225 reads (72%) | catalogued as COSV64885019; called by muse, mutect2, varscan2
- LIMA1 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV57969016; called by muse, mutect2
- PGLYRP4 | c.675C>G p.H225Q | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV62836560; called by muse, mutect2
- PPP1R12C | c.1079C>G p.S360C | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54741404; called by muse, mutect2, varscan2
- RUFY1 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV60164223; called by muse, mutect2, varscan2
- SESN3 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV53587800; called by muse, mutect2, varscan2
- SLC30A2 | c.100C>G p.P34A | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV65333499; called by muse, mutect2, varscan2
- TMEM132D | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757474690, COSV101398995, COSV70623917; called by muse, mutect2, varscan2
- ADAM32 | c.1707G>C p.V569= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV65954135; called by muse, mutect2, varscan2
- ARMC2 | c.2508T>C p.H836= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as rs534134058, COSV64553650; called by muse, mutect2, varscan2
- ELOA2 | c.135G>A p.A45= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs1299824423, COSV55309979; called by muse, mutect2, varscan2
- GPR45 | c.663G>A p.T221= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs141451236; called by muse, mutect2, varscan2
- HFM1 | c.1920T>C p.F640= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV54038641; called by muse, mutect2, varscan2
- ROR1 | c.393C>T p.C131= | Silent (SNP) | VAF 49/144 reads (34%) | catalogued as rs148616064; called by muse, mutect2, varscan2
